Gene-level copy-number profile of tumor specimen TCGA-L5-A88Y-01A from TCGA case TCGA-L5-A88Y, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 76.8 years (28,061 days).
Specimen TCGA-L5-A88Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.01b14a79-dbf8-43c8-b277-6c291a8e46fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A88Y-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/196ba0cd-543a-4cdd-aaa3-41f55865654e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 82; copy number 2: 5,064; copy number 3: 10,183; copy number 4: 14,174; copy number 5: 8,439; copy number 6: 11,903; copy number 7: 4,753; copy number 8: 1,491; copy number 9: 2,633; copy number 10: 184; copy number 11: 56; copy number 14: 633; copy number 15: 7; copy number 21: 44; copy number 24: 116; copy number 36: 36.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,032,884–186,422,432, 1 gene (within-gene range 0–6): LINC01473.
- chr2:186,261,419–186,680,901, 6 genes (within-gene range 0–6): RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV.
- chr7:109,521,981–111,562,517, 13 genes (within-gene range 0–3): AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, AC073326.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,709 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:117,754,139–117,934,942, 4 genes, copy number 14 (within-gene range 6–14): AC009312.1, DDX18, AC009404.1, HTR5BP.
- chr4:156,585,979–159,777,828, 56 genes, copy number 11: AC096736.3, LINC02272, AC096736.2, AC096736.1, PDGFC, AC092608.1, AC092608.3, AC092608.2, AC093325.1, RPPH1-3P, Y_RNA, GLRB, RNU6-582P, GRIA2, AC112240.1, AC093817.2, LINC02433, AC093817.1, Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AC098679.4, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233.
- chr5:58,198–39,721,513, 615 genes, copy number 14 (broad region; genes not listed).
- chr5:104,079,847–107,011,052, 14 genes, copy number 14: LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1, RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950.
- chr6:39,329,990–39,725,408, 1 gene, copy number 21 (within-gene range 3–21): KIF6.
- chr6:39,553,811–58,438,364, 370 genes, copy number 9–36 (broad region; genes not listed).
- chr7:70,972–62,275,678, 1,079 genes, copy number 9 (broad region; genes not listed).
- chr7:98,211,439–102,283,958, 168 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr12:7,711,433–8,227,618, 36 genes, copy number 9: DPPA3, CLEC4C, NANOGNB, Y_RNA, NANOG, Y_RNA, SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6, Y_RNA, AC006511.1, AC006511.4, HSPD1P12, AC006511.2, FOXJ2, C3AR1, NECAP1, AC006511.3, AC006511.5, CLEC4A, POU5F1P3, AC092111.3, GCSHP4, ZNF705A, FAM66C, DEFB109F, AC092111.2, AC092111.1, FAM90A1.
- chr12:9,648,047–9,870,136, 10 genes, copy number 10 (within-gene range 7–10): AC010186.2, AC010186.3, CLEC2D, NPM1P7, LINC02390, CLECL1, CD69, GCNAP1, KLRF1, CLEC2B.
- chr12:24,566,964–24,775,565, 5 genes, copy number 10: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P.
- chr12:24,830,421–24,836,558, 1 gene, copy number 10: AC023796.2.
- chr12:30,795,458–32,107,528, 52 genes, copy number 9 (within-gene range 7–9): AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1.
- chr12:32,109,076–32,109,602, 1 gene, copy number 9: AC048344.4.
- chr20:19,757,606–20,002,459, 1 gene, copy number 9 (within-gene range 8–9): RIN2.
- chr20:20,017,310–64,313,132, 1,079 genes, copy number 9 (broad region; genes not listed).
- chr22:33,014,980–33,922,841, 13 genes, copy number 9: Z83846.1, LINC01640, Z82198.1, Z82198.3, LARGE1, Z82198.2, Z82173.1, MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1.
- chr22:40,410,281–40,636,719, 1 gene, copy number 9 (within-gene range 4–9): MRTFA.
- chr22:40,521,800–47,175,699, 203 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 74. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
